Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA6T, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA6T-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Bladder carcinoma.

Specimens Submitted:

1: Biopsy of trigone

DIAGNOSIS:

1. Biopsy of trigone:

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the non-invasive component:

No definite in situ carcinoma

Local Invasion:

Muscularis propria

Vascular Invasion:

Not identified

Non-Neoplastic Mucosa:

Exhibiting chronic cystitis

Comment: Although the tumor morphologically appears to have focal neuroendocrine differentiation, immunostains for chromogranin and synaptophysin do not support this. Case reviewed in consultation with _____ who concurs.

*ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site Bladder trigone
C67.0
JW 4/30/14*

Pw TSS, 0% neuroendocrine differentiation

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received in _____ labeled "biopsy of trigone", and consists of three pieces of tan soft tissue ranging from 0.4 to 1.4 cm. The specimen is entirely submitted in one cassette(s). TPS taken.

[page 2 of 3]
Page 2 of 3

[page 3 of 3]
[illegible]Page 3 of 3

END OF REPORT

Source: NCI Genomic Data Commons file 59736f95-4317-43c4-9e4e-8832682ecb3a (TCGA-DK-AA6T.7424FFA2-7BE6-4268-BAF4-4589C4F210AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).